TCGA case TCGA-G8-6326 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Retroperitoneum and peritoneum; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f8cf647b-1447-4ac3-8c43-bef07765cabf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C48.1; Tissue or organ of origin: Specified parts of peritoneum; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: primary; Age at diagnosis: 52.7 years (19,238 days); Year of diagnosis: 2009; AJCC staging edition: 6th; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,131 days (5.8 years); Ann Arbor extranodal involvement: Yes; Sites of involvement: Lymph Node, Mesenteric / Omentum / Ascites / Peritoneum, NOS / Other.
   Pathology details: Additional pathology findings: Bone marrow concordant histology; Bone marrow malignant cells: Yes; Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-14; Days to treatment start: 35 days; Days to treatment end: 142 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Cisplatin + Cytarabine + Dexamethasone + Rituximab; Initial disease status: Progressive Disease; Regimen or line of therapy: R-DHAC; Days to treatment start: 263 days; Days to treatment end: 297 days; Number of cycles: 2.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.

Follow-up (5 entries)
- Days to follow up: 1,162 days (3.2 years); Disease response: Tumor Free.
- Days to follow up: 1,441 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 2,131 days (5.8 years); Disease response: Tumor Free.
- ECOG performance status: 0.
- Imaging type: PET; Imaging result: Indeterminate; Timepoint: Within 2 Months After Completion of First-Course Treatment.

Molecular and laboratory tests
- ALK (IHC): Negative.
- BCL6 (IHC): Positive.
- CD10 (IHC): Negative.
- CD15 (IHC): Negative.
- CD20 (IHC): Positive.
- CD23 (IHC): Negative.
- CD30 (IHC): Negative.
- CD5 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative.
- PAX5 (IHC): Positive.
- Involved Tissue, NOS epstein-barr virus (ISH): Negative.
- Lactate Dehydrogenase 964 IU [Blood test normal range upper: 618].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 127.7 kg; Height: 185 cm; BMI: 37.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G8-6326-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.5; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-G8-6326-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-G8-6326-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-G8-6326-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G8-6326-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: mesenteric.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Ascites/Peritoneum; Submitted tumor site: Other Extranodal Site.
- Primary pathology: Extranodal involvment other: Omentum; Extranodal site involvement: 2; Bone marrow sample histology: Concordant Histology.
- Tests performed: LDH level: 964; B cell genotype method: IgH PCR; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: CD23; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: CD79a; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: PAX5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunopheotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunopheotypic analysis tested: CD15; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunopheotypic analysis tested: ALK; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 1, New tumor event: Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: CHOP-14 + Rituximab.
- Drug treatment 5: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Dhac-rituximab; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,131 days; disease-specific survival: no event (censored), 2,131 days; progression-free interval: no event (censored), 2,131 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G8-6326-01A-11D-2209-01): tumor purity 1, ploidy 2, whole-genome doublings 0.
